Somatic mutation profile of tumor specimen TCGA-NC-A5HG-01A (aliquot TCGA-NC-A5HG-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HG, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.2 years (21,608 days).
Specimen TCGA-NC-A5HG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1dcb38-e271-401f-8522-33b64516b33c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HG-10A (Blood Derived Normal), aliquot TCGA-NC-A5HG-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e0543f7-b052-4b4c-bb13-fcb2334d0290

The open-access MAF lists 680 somatic variants for this specimen: 480 protein-altering or splice-affecting, 176 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 420, Silent 176, Nonsense Mutation 33, RNA 9, Intron 8, Splice Site 8, Frame Shift Del 7, Splice Region 6, 3'UTR 4, Nonstop Mutation 2, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 22/27 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>G p.R273G | Missense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A2ML1 | c.3196A>T p.M1066L | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100229427; called by muse, mutect2
- ABCA12 | c.5248C>A p.Q1750K (on ENST00000272895 / NM_173076.3; = p.Q1432K on NM_015657.3) | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99791865; called by muse, mutect2, varscan2
- ABCA13 | c.6826C>G p.L2276V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV101330167; called by muse, mutect2, varscan2
- ABCA6 | c.2907G>C p.K969N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99447624; called by muse, mutect2, varscan2
- ABCA6 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 83/93 reads (89%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99447627; called by muse, mutect2, varscan2
- ABCA7 | c.791-2A>T p.X264_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99566616; called by muse, mutect2, varscan2
- ABCB4 | c.3548C>T p.S1183L (on ENST00000265723 / NM_018849.3; = p.S1176L on NM_000443.4) | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711236; called by muse, mutect2, varscan2
- ABHD13 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV101024255; called by muse, mutect2, varscan2
- ACAN | c.1908C>G p.I636M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100719207, COSV61371563; called by muse, mutect2, varscan2
- ACTBL2 | c.743T>G p.V248G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as COSV101379415, COSV70661460; called by muse, mutect2, varscan2
- ACTG2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV61827559; called by muse, mutect2, varscan2
- ACTL9 | c.266C>A p.S89* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV100185539, COSV61004558; called by muse, mutect2, varscan2
- ADAM18 | c.342C>G p.L114= | Splice Region (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99695852, COSV99696068; called by muse, mutect2, varscan2
- ADAM23 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100006560; called by muse, mutect2, varscan2
- ADAMTS12 | c.2806C>A p.L936I | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100711650; called by muse, mutect2, varscan2
- ADGRD1 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99896951; called by muse, mutect2, varscan2
- ADGRL2 | c.3496G>A p.G1166R (on ENST00000370717 / NM_001366005.1; = p.G1153R on NM_012302.4) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99591425; called by muse, mutect2, varscan2
- ADNP | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.733); catalogued as COSV100823848; called by muse, mutect2, varscan2
- AGBL5 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100549423; called by muse, mutect2, varscan2
- AGL | c.2544C>T p.F848= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99649997; called by muse, mutect2, varscan2
- AGL | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs778230759, COSV99649998; called by muse, mutect2, varscan2
- AGTR1 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); catalogued as COSV62557130, COSV62557404; called by muse, mutect2, varscan2
- AIDA | c.183A>C p.K61N | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100388453; called by muse, mutect2
- AK5 | c.819G>T p.R273S (on ENST00000354567 / NM_174858.3; = p.R247S on NM_012093.4) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643361; called by muse, mutect2, varscan2
- AKAP9 | c.4804C>T p.Q1602* | Nonsense Mutation (SNP) | VAF 47/58 reads (81%) | catalogued as COSV100663057, COSV62360119; called by muse, mutect2, varscan2
- ANGEL1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV99200480; called by muse, mutect2, varscan2
- ANKRD11 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV99970495; called by muse, mutect2, varscan2
- AOPEP | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as COSV52924292, COSV99469412; called by muse, mutect2, varscan2
- APOL2 | c.137+2T>C p.X46_splice | Splice Site (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99969225; called by muse, mutect2, varscan2
- AQP4 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV101270566; called by muse, mutect2, varscan2
- ARAP2 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs371342178, COSV100395220; called by muse, mutect2, varscan2
- ARG1 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV99256276; called by muse, mutect2, varscan2
- ARHGAP17 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV99254003; called by muse, mutect2, varscan2
- ARIH2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100711402; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs748781373, COSV100771989; called by muse, mutect2, varscan2
- ARVCF | c.1001G>T p.G334V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV99599519; called by muse, mutect2
- ASB17 | c.782G>T p.R261I | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99408061; called by muse, mutect2, varscan2
- ASCC1 | c.628A>C p.I210L (on ENST00000342444 / NM_001369085.1; = p.I182L on NM_001198798.2 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.229); catalogued as COSV100403744; called by muse, mutect2, varscan2
- ASH1L | c.7213G>A p.G2405R (on ENST00000368346 / NM_001366177.2; = p.G2400R on NM_018489.3) | Missense Mutation (SNP) | VAF 123/259 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100853591; called by muse, mutect2, varscan2
- ASIC5 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101611174; called by muse, mutect2, varscan2
- ASTN1 | c.3529T>C p.Y1177H | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100707661, COSV100707850; called by muse, mutect2, varscan2
- ATP5F1B | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.199); catalogued as COSV100008225; called by muse, mutect2
- B3GAT3 | c.910-1G>A p.X304_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99606107; called by muse, mutect2
- BABAM1 | c.699G>A p.K233= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100845779; called by muse, mutect2
- BAG6 | c.3130G>A p.A1044T (on ENST00000676571; = p.A997T on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99277592; called by muse, mutect2, varscan2
- BAZ1B | c.2599C>G p.L867V | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as rs782184319, COSV100290112; called by muse, mutect2, varscan2
- BFSP1 | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100925458; called by muse, mutect2
- BICD2 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100794307; called by muse, mutect2
- BIVM-ERCC5 | c.1941C>A p.F647L | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100863933; called by muse, mutect2, varscan2
- BLVRB | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99648057; called by muse, mutect2, varscan2
- BOD1L1 | c.3371C>T p.S1124F | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs748978282, COSV99240348; called by muse, mutect2, varscan2
- BPIFB6 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as rs1476078826, COSV62756956, COSV62757557; called by muse, mutect2, varscan2
- BTAF1 | c.5419G>T p.E1807* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99795791; called by muse, mutect2
- BTD | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100329830; called by muse, mutect2, varscan2
- BYSL | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.418); catalogued as rs149871094; called by muse, mutect2
- C11orf24 | c.1222C>T p.L408F | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV100422597; called by muse, mutect2, varscan2
- C12orf42 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.422); catalogued as COSV100172805; called by muse, mutect2, varscan2
- C1orf116 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100848019; called by muse, mutect2, varscan2
- CACNA1A | c.1712T>C p.I571T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100803166; called by muse, mutect2, varscan2
- CACNA1F | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs781923569, COSV100544981, COSV100545354; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALCRL | c.1207A>G p.K403E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV101131026; called by muse, mutect2, varscan2
- CAMSAP1 | c.3811T>A p.F1271I | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV100410425; called by muse, mutect2, varscan2
- CASP4 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV101274218, COSV67744285; called by muse, mutect2, varscan2
- CASZ1 | c.1128C>A p.Y376* | Nonsense Mutation (SNP) | VAF 34/68 reads (50%) | catalogued as COSV100681306, COSV100682140; called by muse, mutect2, varscan2
- CASZ1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100682144; called by muse, mutect2, varscan2
- CBLN2 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs1462981966, COSV54050470; called by muse, mutect2, varscan2
- CCDC171 | c.3227A>T p.E1076V | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99901891; called by muse, mutect2, varscan2
- CCDC42 | c.294G>T p.Q98H | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99549923; called by muse, mutect2, varscan2
- CCR6 | c.82T>A p.S28T | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100551202; called by muse, mutect2, varscan2
- CD1C | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1450918209, COSV100939454; called by muse, mutect2, varscan2
- CD300A | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.945); catalogued as COSV100177989; called by muse, mutect2, varscan2
- CD5L | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100941171; called by muse, mutect2, varscan2
- CDH19 | c.2059C>A p.Q687K | Missense Mutation (SNP) | VAF 117/146 reads (80%) | SIFT tolerated (0.58); PolyPhen benign (0.377); catalogued as COSV100052283; called by muse, mutect2, varscan2
- CDH2 | c.335A>C p.Q112P | Missense Mutation (SNP) | VAF 125/172 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.287); catalogued as COSV99298453; called by muse, mutect2, varscan2
- CDH9 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs745496451, COSV99152132; called by muse, mutect2, varscan2
- CDKN2A | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 76/96 reads (79%) | catalogued as COSV58682729; called by muse, mutect2, varscan2
- CDR2 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 54/451 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV51677809; called by muse, mutect2, varscan2
- CDYL | c.51A>T p.K17N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV100190102; called by muse, mutect2
- CEP57 | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100334816; called by muse, mutect2, varscan2
- CERS5 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 244/539 reads (45%) | catalogued as COSV100452077; called by muse, mutect2, varscan2
- CERT1 | c.902G>A p.R301K (on ENST00000405807 / NM_001130105.1; = p.R173K on NM_005713.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.521); catalogued as COSV54663981, COSV99783710; called by muse, mutect2, varscan2
- CFAP20 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV99343560; called by muse, mutect2, varscan2
- CFHR4 | c.1492G>T p.V498L (on ENST00000367416 / NM_001201551.2; = p.V252L on NM_006684.5) | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV99261335; called by muse, mutect2, varscan2
- CHPF | c.895C>T p.H299Y | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.05); catalogued as COSV99705289; called by muse, mutect2, varscan2
- CIT | c.3548G>T p.R1183L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV99950907; called by muse, mutect2, varscan2
- CLEC4F | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99713996; called by muse, mutect2, varscan2
- CLMP | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV101507459; called by muse, mutect2, varscan2
- CMYA5 | c.1955C>G p.S652C | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs776552644, COSV101484349; called by muse, mutect2, varscan2
- CNTN6 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as COSV100611804; called by muse, mutect2, varscan2
- CNTNAP4 | c.680C>G p.P227R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs953524982, COSV100273247; called by muse, mutect2, varscan2
- CNTNAP4 | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100273251; called by muse, mutect2, varscan2
- CNTNAP4 | c.3886C>A p.Q1296K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV100273253; called by muse, mutect2, varscan2
- COL11A1 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100617972; called by muse, mutect2, varscan2
- COL15A1 | c.2317G>A p.G773R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897984; called by muse, mutect2, varscan2
- COL24A1 | c.2744G>A p.G915E | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993958; called by muse, mutect2, varscan2
- CPE | c.703T>C p.W235R | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34516004; called by muse, mutect2, varscan2
- CPT1A | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV99681582; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1071C>A p.D357E | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100989849; called by muse, mutect2, varscan2
- CTNND2 | c.1960C>G p.R654G | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773342277, COSV100480793; called by muse, mutect2, varscan2
- CUBN | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402999811, COSV64708504, COSV64719643; called by muse, mutect2, varscan2
- CUL9 | c.5653G>T p.E1885* | Nonsense Mutation (SNP) | VAF 41/124 reads (33%) | catalogued as COSV52733942, COSV99336025; called by muse, mutect2, varscan2
- CYP8B1 | c.553T>A p.L185M | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100296288, COSV60227329; called by muse, mutect2, varscan2
- CYTIP | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 35/131 reads (27%) | catalogued as COSV99938921; called by muse, mutect2, varscan2
- DACH2 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100913868; called by muse, mutect2, varscan2
- DAO | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99948871; called by muse, mutect2, varscan2
- DAO | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs756404040, COSV57323863; called by muse, mutect2, varscan2
- DISP3 | c.3005G>A p.R1002Q | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs750786077, COSV53819770, COSV53821663; called by muse, mutect2, varscan2
- DKK1 | c.43G>C p.A15P | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as COSV100906581; called by muse, mutect2
- DNAH17 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV101103394; called by muse, mutect2, varscan2
- DNAH2 | c.6902T>A p.V2301E | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV101209581; called by muse, mutect2, varscan2
- DNAH5 | c.10233A>T p.K3411N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as COSV99453906; called by muse, mutect2, varscan2
- DNAH7 | c.11395A>G p.I3799V | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as COSV100417441; called by muse, mutect2, varscan2
- DNAH8 | c.6639G>C p.E2213D | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547175; called by muse, mutect2, varscan2
- DNAH9 | c.5024A>T p.Q1675L | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV99307943; called by muse, mutect2, varscan2
- DNAI4 | c.2374G>A p.G792R | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as COSV100925498; called by muse, mutect2, varscan2
- DNAJC13 | c.4901A>T p.N1634I | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99608065; called by muse, mutect2, varscan2
- DNAJC14 | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100423717; called by muse, mutect2, varscan2
- DNAJC6 | c.1267A>G p.S423G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99675597; called by muse, mutect2, varscan2
- DPY19L3 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.076); catalogued as COSV100639301, COSV60480786; called by muse, mutect2
- DSP | c.7776G>C p.K2592N | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV101131736; called by muse, mutect2, varscan2
- DST | c.6058G>A p.G2020S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV99759714; called by muse, mutect2, varscan2
- DSTYK | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs768123228, COSV100904709; called by muse, varscan2
- DTX3 | c.153T>G p.D51E | Missense Mutation (SNP) | VAF 146/334 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.206); catalogued as COSV54090702; called by muse, mutect2, varscan2
- EDRF1 | c.3451G>C p.E1151Q (on ENST00000356792 / NM_001202438.2; = p.E1117Q on NM_015608.2) | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100523966; called by muse, mutect2, varscan2
- ELOA2 | c.1606G>C p.V536L | Missense Mutation (SNP) | VAF 120/143 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1158991586, COSV99797973; called by muse, mutect2, varscan2
- ELOA2 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.79); PolyPhen benign (0.429); catalogued as COSV99797975; called by muse, mutect2, varscan2
- ENTHD1 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57317434; called by muse, mutect2, varscan2
- EPHA1 | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs1034352541, COSV99314649; called by muse, mutect2, varscan2
- EPHA4 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 64/167 reads (38%) | catalogued as COSV56028926, COSV99917439; called by muse, mutect2, varscan2
- EPHB3 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100383273; called by muse, mutect2, varscan2
- ERBB3 | c.3889G>A p.G1297R | Missense Mutation (SNP) | VAF 58/256 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV99917800; called by muse, mutect2, varscan2
- EXOC6 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99592481; called by muse, mutect2, varscan2
- F9 | c.166G>T p.V56F | Missense Mutation (SNP) | VAF 102/127 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99496882; called by muse, mutect2, varscan2
- FAM149A | c.2159C>A p.T720K (on ENST00000356371 / NM_001367768.2; = p.T429K on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs764703223, COSV99906725; called by muse, mutect2, varscan2
- FAM47B | c.1025C>A p.S342Y | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100264615; called by muse, mutect2, varscan2
- FAM47C | c.1417C>A p.H473N | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.917); catalogued as rs1556332383, COSV100792932, COSV63723569; called by muse, mutect2, varscan2
- FAM78B | c.444G>T p.W148C | Missense Mutation (SNP) | VAF 95/184 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597783; called by muse, mutect2, varscan2
- FAM83G | c.1667G>A p.R556Q | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs767831731, COSV100525487; called by muse, mutect2, varscan2
- FASTKD5 | c.1553A>G p.D518G | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.467); catalogued as rs1313015563, COSV99418558; called by muse, mutect2, varscan2
- FBXO3 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV99682327; called by muse, mutect2, varscan2
- FBXO30 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 115/155 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99395408; called by muse, mutect2, varscan2
- FCGR2A | c.400C>T p.Q134* (on ENST00000271450 / NM_001136219.3; = p.Q133* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 52/134 reads (39%) | catalogued as COSV99615701; called by muse, mutect2, varscan2
- FGFBP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99469176; called by muse, mutect2
- FGFR1 | c.1834G>C p.E612Q (on ENST00000447712 / NM_023110.3; = p.E610Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.715); catalogued as rs1343172545, COSV100249147; called by muse, mutect2
- FKBP14 | c.141G>C p.L47F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV99321593; called by muse, mutect2, varscan2
- FLG | c.7354C>T p.H2452Y | Missense Mutation (SNP) | VAF 335/671 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); catalogued as rs752287771, COSV100912131; called by muse, mutect2, varscan2
- FMNL3 | c.603C>T p.L201= | Splice Region (SNP) | VAF 23/75 reads (31%) | catalogued as rs1182449285, COSV99526943; called by muse, mutect2, varscan2
- FNDC7 | c.1319A>T p.N440I | Missense Mutation (SNP) | VAF 105/193 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV99601672; called by muse, mutect2, varscan2
- FOXD4L6 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1273284403; called by mutect2, varscan2
- FRY | c.4219G>C p.G1407R | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969884, COSV66565198; called by muse, mutect2
- FRYL | c.998G>A p.W333* | Nonsense Mutation (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99978031; called by muse, mutect2, varscan2
- FSCB | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as rs757049582, COSV100469833; called by muse, mutect2, varscan2
- FTO | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101151199; called by muse, mutect2, varscan2
- FUBP3 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 47/61 reads (77%) | catalogued as COSV100156309; called by muse, mutect2, varscan2
- FXR1 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99976664; called by muse, mutect2, varscan2
- GAB4 | c.1288+2T>G p.X430_splice | Splice Site (SNP) | VAF 44/336 reads (13%) | catalogued as COSV101272101; called by muse, mutect2, varscan2
- GALNT13 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs754730499, COSV101224177; called by muse, mutect2, varscan2
- GAS2L1 | c.1664C>G p.A555G | Missense Mutation (SNP) | VAF 21/632 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99329705; called by muse, mutect2
- GAS2L3 | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV99903147; called by muse, mutect2, varscan2
- GBGT1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.333); catalogued as COSV100923170; called by muse, mutect2, varscan2
- GCH1 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99582078; called by muse, mutect2, varscan2
- GCM2 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101069617; called by muse, mutect2, varscan2
- GDPD3 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 94/484 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53777266; called by muse, mutect2, varscan2
- GFPT1 | c.417A>C p.K139N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV100622993; called by muse, mutect2, varscan2
- GGH | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99479028; called by muse, mutect2, varscan2
- GIMAP1 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100212307; called by muse, mutect2
- GOLGB1 | c.740A>C p.E247A | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100511498; called by muse, mutect2, varscan2
- GOLGB1 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 45/103 reads (44%) | catalogued as COSV100511500; called by muse, mutect2, varscan2
- GPC5 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100995859; called by muse, mutect2, varscan2
- GPR146 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99866533; called by muse, mutect2, varscan2
- GPR158 | c.1774T>C p.W592R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV100894258; called by muse, mutect2, varscan2
- GPR39 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV61425015; called by muse, mutect2, varscan2
- GPR50 | c.1729A>G p.S577G | Missense Mutation (SNP) | VAF 82/107 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99506635; called by muse, mutect2, varscan2
- GRIA1 | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs759869812, COSV53590645; called by muse, mutect2, varscan2
- GRIA3 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.072); catalogued as COSV52072938; called by muse, mutect2, varscan2
- GUCY1A2 | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56479357, COSV99976720; called by muse, mutect2, varscan2
- H2BC8 | c.83A>G p.K28R | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs1218876434, COSV99773380; called by muse, mutect2, varscan2
- HIVEP1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1403861864, COSV101045706; called by muse, mutect2, varscan2
- HMX3 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); catalogued as COSV100774168, COSV63501554; called by muse, mutect2, varscan2
- HNF1A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV99982979; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 44/113 reads (39%) | catalogued as COSV100079544; called by muse, mutect2, varscan2
- HOOK1 | c.366G>C p.Q122H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969245; called by muse, mutect2, varscan2
- HPR | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.037); catalogued as rs1210252330, COSV99931029; called by muse, mutect2, varscan2
- HYDIN | c.202T>A p.L68M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99865140; called by muse, mutect2, varscan2
- IFNAR1 | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as COSV99531817; called by muse, varscan2
- IFNAR1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV99531819; called by muse, varscan2
- IFT172 | c.71G>A p.W24* | Nonsense Mutation (SNP) | VAF 75/156 reads (48%) | catalogued as COSV99563259; called by muse, mutect2, varscan2
- IGF1R | c.1017G>C p.K339N | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51345326; called by muse, mutect2
- IGFBP3 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV99298501; called by muse, mutect2, varscan2
- IGLV11-55 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368002354, COSV66504586; called by muse, mutect2, varscan2
- IGSF10 | c.3991A>G p.T1331A | Missense Mutation (SNP) | VAF 165/411 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99194158; called by muse, mutect2, varscan2
- IKBIP | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100689879; called by muse, mutect2, varscan2
- IL11RA | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99426573; called by muse, mutect2, varscan2
- IMPDH1 | c.867C>G p.I289M (on ENST00000470772 / NM_001142573.2; = p.I375M on NM_000883.4) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV100118801; called by muse, mutect2, varscan2
- IRX3 | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100315407; called by muse, varscan2
- ITGA1 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99252109; called by muse, mutect2, varscan2
- ITPR2 | c.5811+1G>A p.X1937_splice | Splice Site (SNP) | VAF 37/114 reads (32%) | catalogued as COSV101190152; called by muse, mutect2, varscan2
- JAG1 | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV99653512; called by muse, mutect2, varscan2
- KANK4 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100587692; called by muse, mutect2, varscan2
- KCNC2 | c.858A>C p.E286D | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100129821; called by muse, mutect2, varscan2
- KCNH7 | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100149681, COSV59791969; called by muse, mutect2
- KIAA0319L | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.869); catalogued as COSV100357674; called by muse, mutect2, varscan2
- KIF16B | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV100734443; called by muse, mutect2, varscan2
- KIF20B | c.5026C>T p.P1676S (on ENST00000371728 / NM_001284259.2; = p.P1636S on NM_016195.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV53309730; called by muse, mutect2, varscan2
- KIF24 | c.2072G>A p.G691E | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV100799328; called by muse, mutect2, varscan2
- KLHL22 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.637); catalogued as COSV100186240; called by muse, mutect2, varscan2
- KLHL25 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); catalogued as COSV100563722; called by muse, mutect2, varscan2
- KLHL40 | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV55132863, COSV99825750; called by muse, mutect2, varscan2
- KMT2A | c.2894G>A p.G965E | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV100629786; called by muse, mutect2, varscan2
- KMT2C | c.2530C>T p.Q844* | Nonsense Mutation (SNP) | VAF 72/137 reads (53%) | catalogued as COSV100076238, COSV51457483, COSV51459474; called by muse, mutect2, varscan2
- KMT2E | c.3629A>G p.D1210G | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs765081718, COSV99996959; called by muse, mutect2, varscan2
- KRTAP15-1 | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100481659; called by muse, mutect2, varscan2
- KRTAP6-3 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | PolyPhen probably damaging (0.989); catalogued as COSV66963335, COSV99060498; called by muse, mutect2, varscan2
- LAMA5 | c.2254G>T p.G752W | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442135; called by muse, mutect2, varscan2
- LATS1 | c.1882G>T p.E628* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99486652; called by muse, mutect2, varscan2
- LATS1 | c.1881G>C p.R627S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99486654; called by muse, mutect2, varscan2
- LCOR | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100603862; called by muse, mutect2, varscan2
- LFNG | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 47/51 reads (92%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1219423116, COSV101273453; called by muse, mutect2, varscan2
- LIME1 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100203294; called by muse, mutect2, varscan2
- LMOD3 | c.1598C>A p.T533N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101342027; called by muse, mutect2, varscan2
- LRATD2 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100513659; called by muse, mutect2, varscan2
- LRP1B | c.11558C>A p.T3853K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV101260546; called by muse, mutect2, varscan2
- LRP1B | c.6142G>A p.D2048N | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67238170; called by muse, mutect2, varscan2
- LRP6 | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99744424; called by muse, mutect2, varscan2
- LRRC6 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99138554; called by muse, mutect2, varscan2
- LRRCC1 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV100835589; called by muse, mutect2, varscan2
- LYN | c.1468T>A p.F490I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101571254; called by muse, mutect2, varscan2
- MAGEB1 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV100975101; called by muse, mutect2, varscan2
- MAIP1 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99705333; called by muse, mutect2, varscan2
- MAN2A1 | c.1274A>G p.D425G | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99811854; called by muse, mutect2, varscan2
- MAP3K12 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 51/300 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99913535; called by muse, mutect2, varscan2
- MAP3K12 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 72/379 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99913537; called by muse, mutect2, varscan2
- MAPKBP1 | c.4165C>T p.P1389S (on ENST00000456763 / NM_001128608.2; = p.P1383S on NM_014994.3) | Missense Mutation (SNP) | VAF 51/190 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99530121; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 22/74 reads (30%) | catalogued as rs777328830; called by mutect2, varscan2
- MBD1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs759684535, COSV99497180; called by muse, mutect2, varscan2
- MBTPS1 | c.1278G>T p.L426F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597786; called by muse, mutect2, varscan2
- MDGA2 | c.2692G>A p.G898R (on ENST00000399232 / NM_001113498.2; = p.G600R on NM_182830.4) | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV62118623; called by muse, mutect2, varscan2
- MED10 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV99740404; called by muse, mutect2, varscan2
- MED23 | c.4044G>C p.M1348I | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV99256278; called by muse, mutect2, varscan2
- MEGF11 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1422798142, COSV99989131; called by muse, mutect2
- METTL23 | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1341775184, COSV100334263; called by muse, mutect2, varscan2
- METTL25 | c.532-1G>A p.X178_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99942688; called by muse, mutect2, varscan2
- MFNG | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV99325350; called by muse, mutect2, varscan2
- MFSD4A | c.448G>A p.G150S | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901699; called by muse, mutect2, varscan2
- MLH1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs1064794851, COSV51622330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MLLT6 | c.1623G>C p.L541F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1284372753; called by muse, mutect2, varscan2
- MMAB | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99904673; called by muse, mutect2, varscan2
- MMS19 | c.1459G>T p.G487C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV100513096; called by muse, mutect2, varscan2
- MORC3 | c.1209G>A p.Q403= | Splice Region (SNP) | VAF 36/141 reads (26%) | catalogued as rs745902580, COSV101247761; called by muse, mutect2, varscan2
- MORC4 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 96/124 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55247292, COSV99716858; called by muse, mutect2, varscan2
- MPP6 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 69/78 reads (88%) | catalogued as COSV99757837; called by muse, mutect2, varscan2
- MST1 | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.072); catalogued as COSV99611116; called by muse, mutect2, varscan2
- MTNR1A | c.456G>C p.W152C | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100208323; called by muse, mutect2, varscan2
- MTR | c.3794A>T p.D1265V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100855542; called by muse, mutect2, varscan2
- MUC1 | c.3499G>A p.G1167S (on ENST00000611571 / NM_001371720.1; = p.G178S on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252688154, COSV100104828; called by muse, mutect2, varscan2
- MUC16 | c.37150G>A p.G12384S | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.051); catalogued as COSV101201495; called by muse, mutect2, varscan2
- MUC16 | c.12285G>T p.M4095I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.181); catalogued as COSV101201496; called by muse, mutect2, varscan2
- MUC5AC | c.14404G>T p.D4802Y | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100611585; called by muse, mutect2, varscan2
- MYO10 | c.4440G>C p.K1480N | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99946222; called by muse, mutect2, varscan2
- MYO5C | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV99955425; called by muse, mutect2, varscan2
- NAALAD2 | c.2018G>C p.G673A | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV100428792; called by muse, mutect2, varscan2
- NAF1 | c.919C>G p.P307A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99919363; called by muse, mutect2, varscan2
- NBEA | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100083957; called by muse, mutect2, varscan2
- NCR3 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV53002449; called by muse, mutect2
- NEB | c.11773C>T p.L3925F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99424991; called by muse, mutect2
- NELL2 | c.455A>T p.K152M | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100420750; called by muse, mutect2, varscan2
- NF1 | c.2614G>T p.E872* | Nonsense Mutation (SNP) | VAF 41/62 reads (66%) | catalogued as COSV100648206, COSV62194200; called by muse, mutect2, varscan2
- NIPBL | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV99242544; called by muse, mutect2, varscan2
- NMS | c.462A>T p.*154Cext*? | Nonstop Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100966656; called by muse, mutect2, varscan2
- NOL6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99955174; called by muse, mutect2, varscan2
- NOP53 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV99884582; called by muse, mutect2, varscan2
- NPS | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 248/608 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1565126765, COSV101219430; called by muse, mutect2, varscan2
- NSD1 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 26/40 reads (65%) | catalogued as COSV100729779; called by muse, mutect2, varscan2
- NTRK3 | c.1889+2T>C p.X630_splice | Splice Site (SNP) | VAF 23/56 reads (41%) | catalogued as COSV100713822; called by muse, mutect2, varscan2
- OBSCN | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.435); catalogued as COSV99481113, COSV99484007; called by muse, mutect2, varscan2
- OBSCN | c.4394A>T p.E1465V | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.643); catalogued as COSV99484014; called by muse, mutect2, varscan2
- OLIG2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324342; called by muse, mutect2, varscan2
- OPRM1 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.151); catalogued as rs777099271, COSV100002380; called by muse, varscan2
- OR10G4 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as COSV100304980; called by muse, mutect2, varscan2
- OR11H6 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV100209964, COSV59644102; called by muse, mutect2, varscan2
- OR2M3 | c.214A>G p.M72V | Missense Mutation (SNP) | VAF 205/796 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV101513513; called by muse, mutect2, varscan2
- OR2T11 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758684399, COSV100424952; called by muse, mutect2, varscan2
- OR2T27 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV100788394; called by muse, mutect2, varscan2
- OR2W3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV64457068; called by muse, mutect2, varscan2
- OR4S1 | c.218C>G p.S73C | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV60678608; called by muse, mutect2, varscan2
- OR51B4 | c.910T>C p.F304L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100972030; called by muse, mutect2, varscan2
- OR52B4 | c.760T>A p.Y254N | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101281608; called by muse, mutect2, varscan2
- OR5B3 | c.85T>A p.F29I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as COSV100512068; called by muse, mutect2, varscan2
- OR5F1 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.182); catalogued as COSV53548788; called by muse, mutect2, varscan2
- OR5L1 | c.813C>A p.D271E | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV100450254; called by muse, mutect2, varscan2
- OR7A5 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.443); catalogued as COSV100457939; called by muse, mutect2, varscan2
- OTUD7B | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64917940; called by muse, mutect2, varscan2
- PACS1 | c.2694G>C p.K898N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100270546; called by muse, mutect2, varscan2
- PCDH15 | c.1517C>G p.T506R | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs367937228, COSV100227248, COSV57271858; called by muse, mutect2, varscan2
- PCDH17 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV100931548; called by muse, mutect2, varscan2
- PCK1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV100100940; called by muse, mutect2, varscan2
- PCLO | c.10433A>G p.D3478G | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100437482; called by muse, mutect2, varscan2
- PCLO | c.7925C>T p.S2642F | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100437484; called by muse, mutect2, varscan2
- PCNA | c.485G>A p.C162Y | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99177022; called by muse, mutect2, varscan2
- PCNX1 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99457149; called by muse, mutect2, varscan2
- PDE1C | c.1404G>A p.S468= | Splice Region (SNP) | VAF 61/167 reads (37%) | catalogued as rs140362011, COSV58520292; called by muse, mutect2, varscan2
- PDE4DIP | c.5767A>G p.R1923G | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs782644802, COSV100521662; called by muse, mutect2, varscan2
- PDLIM5 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100524318; called by muse, mutect2, varscan2
- PGM2L1 | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.401); catalogued as COSV99995190; called by muse, mutect2
- PHF20L1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as COSV99622098; called by muse, mutect2, varscan2
- PHLPP2 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100673813; called by muse, mutect2, varscan2
- PHOX2B | c.357G>C p.E119D | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99891713; called by muse, mutect2, varscan2
- PIK3C2B | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 193/398 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); catalogued as COSV65803521; called by muse, mutect2, varscan2
- PIP4K2C | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100724029; called by muse, mutect2, varscan2
- PKHD1L1 | c.5098T>A p.C1700S | Missense Mutation (SNP) | VAF 252/348 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101006275; called by muse, mutect2, varscan2
- PLCB4 | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.931); catalogued as COSV53823855; called by muse, mutect2, varscan2
- PLD5 | c.1146A>T p.L382F (on ENST00000442594; = p.L320F on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV100142465; called by muse, mutect2, varscan2
- PLEKHG2 | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.007); catalogued as rs867759713, COSV52685137, COSV99218078; called by muse, mutect2, varscan2
- PLPPR4 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 42/73 reads (58%) | catalogued as COSV100926922; called by muse, mutect2, varscan2
- PLRG1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs973995113, COSV57423558; called by muse, mutect2, varscan2
- PLSCR2 | c.527G>A p.C176Y (on ENST00000497985 / NM_001199978.1; = p.C103Y on NM_020359.2) | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100367926; called by muse, mutect2, varscan2
- PLXDC2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV101025822; called by muse, mutect2, varscan2
- PLXNA1 | c.4054G>A p.E1352K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs568444014, COSV99304035; called by muse, mutect2, varscan2
- POU1F1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as COSV100622775; called by muse, varscan2
- PPM1K | c.245A>T p.K82M | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV99901157; called by muse, mutect2, varscan2
- PPP1R16A | c.97C>G p.Q33E | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99477644; called by muse, mutect2, varscan2
- PPP1R27 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs770458996, COSV100367371; called by muse, varscan2
- PPP6R1 | c.1715A>G p.N572S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as rs760757851, COSV101337014; called by muse, mutect2, varscan2
- PRAM1 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725087; called by muse, mutect2, varscan2
- PRAMEF5 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100871347; called by muse, mutect2, varscan2
- PSG8 | c.557G>A p.S186N | Missense Mutation (SNP) | VAF 223/429 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100126597; called by muse, mutect2, varscan2
- PSMD12 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100635426; called by muse, mutect2
- PTGER2 | c.1067C>A p.A356D | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99817739; called by muse, mutect2, varscan2
- PTGER3 | c.1151G>T p.W384L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV100139638; called by muse, mutect2, varscan2
- PTGER3 | c.1150T>C p.W384R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as COSV60687469; called by muse, mutect2, varscan2
- PTK2 | c.2299C>T p.L767F | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1038528814, COSV61783726; called by muse, mutect2, varscan2
- PTPRB | c.4737C>G p.I1579M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99718869; called by muse, mutect2
- PTPRF | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs1160984093, COSV100741219; called by muse, mutect2, varscan2
- PUM1 | c.3560G>T p.*1187Lext*71 | Nonstop Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV57092523, COSV99928886; called by muse, mutect2, varscan2
- PXDNL | c.3916G>A p.G1306R | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as rs1405837146, COSV100686136; called by muse, mutect2, varscan2
- QRFPR | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 108/129 reads (84%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.199); catalogued as COSV100543962, COSV57677535; called by muse, mutect2, varscan2
- RABL6 | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.895); catalogued as COSV100273723; called by muse, mutect2, varscan2
- RAD51B | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101185399; called by muse, mutect2, varscan2
- RALGAPA2 | c.2819G>A p.G940E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99174945; called by muse, mutect2
- RANBP1 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as COSV99350309; called by muse, mutect2
- RCSD1 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.722); catalogued as COSV100827781; called by muse, mutect2, varscan2
- RELN | c.8579G>T p.C2860F | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as COSV100634893; called by muse, mutect2, varscan2
- RELN | c.7982C>A p.S2661* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100634895; called by muse, mutect2
- REXO1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99402621; called by muse, mutect2, varscan2
- RGS1 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100817568; called by muse, mutect2, varscan2
- RGS9BP | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100043143; called by muse, mutect2, varscan2
- RIMS2 | c.1258G>C p.G420R (on ENST00000666250 / NM_001348490.2; = p.G228R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.289); catalogued as COSV51733927, COSV99197696; called by muse, mutect2, varscan2
- RPL41 | c.5G>C p.R2T | Missense Mutation (SNP) | VAF 55/295 reads (19%) | catalogued as COSV99230615; called by muse, mutect2, varscan2
- RRN3 | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as rs760370682, COSV99549099; called by muse, mutect2, varscan2
- RYR2 | c.638G>T p.S213I | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100772729; called by muse, mutect2, varscan2
- S1PR1 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV100541672; called by muse, mutect2, varscan2
- SAGE1 | c.1693G>C p.G565R | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187874; called by muse, mutect2, varscan2
- SCN2A | c.3779A>G p.K1260R | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99332894; called by muse, mutect2, varscan2
- SCNN1G | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV100264492; called by muse, mutect2, varscan2
- SELP | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99741067; called by muse, mutect2, varscan2
- SEMA3E | c.1728G>C p.Q576H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV100319558; called by muse, mutect2
- SEMA5A | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101228702; called by muse, mutect2, varscan2
- SERPINA5 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV61574974, COSV61575020; called by muse, mutect2, varscan2
- SERPINA9 | c.644C>G p.P215R | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100098757; called by muse, mutect2, varscan2
- SESTD1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100090883; called by muse, mutect2, varscan2
- SETBP1 | c.3926A>G p.Y1309C | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs778118309, COSV99954837; called by muse, mutect2, varscan2
- SETD1A | c.155C>G p.S52* | Nonsense Mutation (SNP) | VAF 36/269 reads (13%) | catalogued as COSV99353659; called by muse, mutect2, varscan2
- SHANK1 | c.5603C>A p.A1868D | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99521989; called by muse, mutect2, varscan2
- SIGLEC1 | c.471C>G p.D157E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.318); catalogued as COSV99170734; called by muse, mutect2
- SKAP1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV100412281; called by muse, mutect2, varscan2
- SLC12A9 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.066); catalogued as COSV99308164; called by muse, mutect2, varscan2
- SLC12A9 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 62/606 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99308166; called by muse, mutect2, varscan2
- SLC13A4 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100818948; called by muse, mutect2
- SLC22A23 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.912); catalogued as COSV100978386; called by muse, mutect2, varscan2
- SLC24A2 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV99647413; called by muse, mutect2, varscan2
- SLC28A1 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1332898912, COSV99723512; called by muse, mutect2, varscan2
- SLC29A2 | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100237204; called by muse, mutect2, varscan2
- SLC35B4 | c.926T>A p.M309K | Missense Mutation (SNP) | VAF 110/126 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV101043186; called by muse, mutect2, varscan2
- SLC7A7 | c.573A>C p.K191N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99591849; called by muse, mutect2
- SLC8A1 | c.2626G>C p.V876L | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247364, COSV60500744; called by muse, mutect2, varscan2
- SLCO1A2 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100262644; called by muse, mutect2, varscan2
- SLITRK1 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV101000056; called by muse, mutect2, varscan2
- SMG7 | c.2242C>T p.P748S | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.996); catalogued as COSV100750559; called by muse, mutect2, varscan2
- SMPD1 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100193048; called by muse, mutect2, varscan2
- SMYD1 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV101352512; called by muse, mutect2, varscan2
- SP140 | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100614056; called by muse, mutect2
- SPAG17 | c.5913T>A p.S1971R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100310482; called by muse, mutect2, varscan2
- SPEF2 | c.5252C>T p.A1751V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.138); catalogued as COSV100289392; called by muse, mutect2, varscan2
- SPEN | c.5071C>T p.P1691S | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs532673015, COSV101005580; called by muse, mutect2, varscan2
- SPP1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.112); catalogued as rs1225510546, COSV99421231; called by muse, mutect2
- SPTA1 | c.5042T>A p.V1681D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV100935531; called by muse, mutect2, varscan2
- SRGAP3 | c.2769C>G p.I923M | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100841404; called by muse, mutect2
- SULF1 | c.2588G>T p.G863V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV52675542, COSV99484288; called by muse, mutect2, varscan2
- SYTL5 | c.379C>G p.R127G | Missense Mutation (SNP) | VAF 49/60 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52899828, COSV99937627; called by muse, mutect2, varscan2
- TAF1B | c.972A>C p.L324F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99722561; called by muse, mutect2, varscan2
- TCHP | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.85); catalogued as COSV100452643, COSV57166180; called by muse, mutect2, varscan2
- TDG | c.179G>C p.G60A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.247); catalogued as COSV99904340; called by muse, mutect2
- TDO2 | c.731A>T p.K244I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV101539798; called by muse, mutect2
- TGIF2LX | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV99383526; called by muse, mutect2, varscan2
- TIAM1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54546344; called by muse, mutect2, varscan2
- TIE1 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100992179; called by muse, mutect2, varscan2
- TIE1 | c.2571G>A p.M857I | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV100992180; called by muse, mutect2, varscan2
- TLR3 | c.2518A>G p.I840V | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs1411997457, COSV99711201; called by muse, mutect2, varscan2
- TLR8 | c.2408G>A p.C803Y (on ENST00000218032 / NM_138636.5; = p.C821Y on NM_016610.4) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99487280; called by muse, mutect2
- TMEM63A | c.1571G>C p.S524T | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834447; called by muse, mutect2, varscan2
- TMEM67 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV100019869; called by muse, mutect2, varscan2
- TMEM72 | c.608A>T p.N203I | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV101273579; called by muse, mutect2, varscan2
- TMX4 | c.574T>C p.F192L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99851642; called by muse, mutect2, varscan2
- TNC | c.2524G>T p.V842L | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.175); catalogued as COSV100406229, COSV60787818; called by muse, mutect2, varscan2
- TNS1 | c.937G>A p.G313S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99411831; called by muse, mutect2, varscan2
- TOP1 | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100793958; called by muse, mutect2, varscan2
- TREM1 | c.206G>C p.C69S | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55149776, COSV99776298; called by muse, mutect2, varscan2
- TRIM33 | c.2728C>T p.H910Y | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100635734; called by muse, mutect2, varscan2
- TRPC4 | c.1430C>G p.A477G | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100157846; called by muse, mutect2, varscan2
- TRPM3 | c.1642G>C p.E548Q (on ENST00000357533 / NM_001366142.2; = p.E393Q on NM_024971.6) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV100678661; called by muse, mutect2, varscan2
- TRPS1 | c.1778C>T p.S593F (on ENST00000220888 / NM_001330599.2; = p.S606F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV99634176; called by muse, mutect2, varscan2
- TRRAP | c.9802C>T p.P3268S (on ENST00000359863 / NM_001244580.1; = p.P3239S on NM_003496.3) | Missense Mutation (SNP) | VAF 97/873 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.083); catalogued as COSV100722914; called by muse, mutect2, varscan2
- TSPAN16 | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 87/122 reads (71%) | catalogued as COSV100368480, COSV57442014; called by muse, mutect2, varscan2
- TTLL6 | c.1023C>G p.Y341* (on ENST00000393382 / NM_001130918.3; = p.Y34* on NM_173623.3) | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV100938223; called by muse, mutect2, varscan2
- TTN | c.79600T>A p.W26534R (on ENST00000591111; = p.W19110R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | PolyPhen probably damaging (0.999); catalogued as COSV100628880; called by muse, mutect2, varscan2
- TTN | c.63830C>A p.A21277E (on ENST00000591111; = p.A13853E on NM_003319.4) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | PolyPhen probably damaging (0.998); catalogued as rs1194010406, COSV100628884; called by muse, mutect2, varscan2
- TTN | c.51899C>T p.A17300V (on ENST00000591111; = p.A9876V on NM_003319.4) | Missense Mutation (SNP) | VAF 53/134 reads (40%) | PolyPhen benign (0.006); catalogued as rs754264431, COSV100628887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.43248T>G p.S14416R (on ENST00000591111; = p.S6992R on NM_003319.4) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | PolyPhen possibly damaging (0.804); catalogued as COSV100628892; called by muse, mutect2, varscan2
- TTN | c.28112C>T p.A9371V (on ENST00000591111; = p.A8444V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/24 reads (71%) | PolyPhen benign (0.007); catalogued as COSV100628898; called by muse, mutect2, varscan2
- UBAP1 | c.1270C>G p.L424V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99903572; called by muse, mutect2, varscan2
- UBASH3B | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 89/128 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418778; called by muse, mutect2, varscan2
- UBE2G1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs1488546307, COSV101213104; called by muse, mutect2, varscan2
- UBE4B | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.027); catalogued as COSV99477586; called by muse, mutect2, varscan2
- UBQLN3 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV61164073; called by muse, mutect2, varscan2
- UGT8 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV100179364; called by muse, mutect2, varscan2
- ULK1 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100417257; called by muse, mutect2, varscan2
- UNC5D | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV54840357, COSV99778552; called by muse, mutect2, varscan2
- UNC79 | c.3529G>A p.A1177T (on ENST00000393151 / NM_001346218.2; = p.A1000T on NM_020818.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99829774; called by muse, mutect2, varscan2
- VARS1 | c.1786C>T p.H596Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791857; called by muse, mutect2, varscan2
- VPS13C | c.8074G>T p.E2692* (on ENST00000644861 / NM_020821.3; = p.E2649* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs1350966662, COSV99830117; called by muse, mutect2, varscan2
- VSIG8 | c.4A>T p.R2* | Nonsense Mutation (SNP) | VAF 58/116 reads (50%) | catalogued as COSV100928839; called by muse, mutect2, varscan2
- VTCN1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV60222095, COSV60223599; called by muse, mutect2, varscan2
- VWA8 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 34/46 reads (74%) | catalogued as COSV99865092; called by muse, mutect2, varscan2
- WASL | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.203); catalogued as COSV99771837; called by muse, varscan2
- WNK1 | c.2833G>T p.G945C | Missense Mutation (SNP) | VAF 60/745 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100268548; called by muse, mutect2
- XIRP2 | c.5096C>T p.S1699L (on ENST00000628543; = p.S1874L on NM_152381.6) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV99747090; called by muse, mutect2, varscan2
- XKR4 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100531339; called by muse, mutect2, varscan2
- XRCC6 | c.1754G>T p.C585F | Missense Mutation (SNP) | VAF 78/151 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100777916; called by muse, mutect2, varscan2
- YME1L1 | c.1493T>G p.F498C (on ENST00000326799 / NM_139312.3; = p.F441C on NM_014263.4) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58759008; called by muse, mutect2, varscan2
- ZAN | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1235359835, COSV100770293; called by muse, mutect2, varscan2
- ZFP69 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV101018374; called by muse, mutect2, varscan2
- ZIC1 | c.480C>A p.N160K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377681059, COSV99292394; called by muse, mutect2, varscan2
- ZNF12 | c.1993G>C p.E665Q (on ENST00000405858 / NM_016265.4; = p.E627Q on NM_006956.3) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as COSV100703870; called by muse, mutect2, varscan2
- ZNF20 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 131/208 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV100503164; called by muse, mutect2, varscan2
- ZNF235 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs773680891, COSV52157229; called by muse, mutect2, varscan2
- ZNF253 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV100849586, COSV63036794; called by muse, mutect2, varscan2
- ZNF331 | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99467908; called by muse, mutect2, varscan2
- ZNF451 | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100675096; called by muse, mutect2, varscan2
- ZNF530 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs757338523, COSV100252741; called by muse, mutect2, varscan2
- ZNF564 | c.1600G>T p.V534L | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100213284; called by muse, mutect2, varscan2
- ZNF644 | c.3542G>A p.G1181E | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.233); catalogued as COSV100494713; called by muse, mutect2, varscan2
- ZNF670 | c.494G>C p.S165T | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100829343; called by muse, mutect2, varscan2
- ZNF7 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296123; called by muse, mutect2, varscan2
- ZNF709 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV67195935; called by muse, varscan2
- ZNF750 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV99489954; called by muse, mutect2, varscan2
- ZNF835 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.169); catalogued as COSV101606400; called by muse, mutect2, varscan2
- ZNF91 | c.1044A>T p.K348N | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100323428; called by muse, mutect2, varscan2
- ZNFX1 | c.116C>G p.P39R | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.034); catalogued as COSV100871006; called by muse, mutect2, varscan2
- ZSWIM8 | c.5042G>A p.R1681Q (on ENST00000605216 / NM_001242487.2; = p.R1686Q on NM_015037.3) | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55214093; called by muse, mutect2, varscan2
- CAND2 | c.1171_1173dup p.N391dup (on ENST00000456430 / NM_001162499.2; = p.N298dup on NM_012298.3) | In Frame Ins (INS) | VAF 34/70 reads (49%) | called by pindel, varscan2
- CFAP74 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAT1 | c.10884del p.V3629Cfs*11 | Frame Shift Del (DEL) | VAF 41/66 reads (62%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- HGH1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- IGHA1 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2D | c.7769_7794del p.S2590Wfs*56 | Frame Shift Del (DEL) | VAF 15/51 reads (29%) | called by mutect2, pindel, varscan2
- MAP3K14 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC15 | c.844+1del p.X282_splice | Splice Site (DEL) | VAF 34/65 reads (52%) | called by mutect2, pindel, varscan2
- MYO19 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2
- NBPF20 | c.278G>T p.R93M | Missense Mutation (SNP) | VAF 124/300 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5H15 | c.426_428delinsAA p.R143Sfs*3 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | called by pindel, varscan2*
- PGM2L1 | c.1059dup p.G354Rfs*3 | Frame Shift Ins (INS) | VAF 19/66 reads (29%) | called by mutect2, varscan2
- PGM2L1 | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- PTPRR | c.114del p.K39Sfs*18 | Frame Shift Del (DEL) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- STK36 | c.882del p.K295Rfs*8 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- TOP2B | c.4799_4823del p.T1600Nfs*55 (on ENST00000264331 / NM_001330700.2; = p.T1595Nfs*55 on NM_001068.3) | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- ZIC3 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF28 | c.696del p.K232Nfs*4 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- ABCC6 | c.3312G>C p.L1104= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs559504956, COSV99229570; called by muse, mutect2, varscan2
- ADAMTS18 | c.2589C>T p.V863= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99274084; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4260C>A p.I1420= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV101000531; called by muse, mutect2, varscan2
- ADGRL3 | c.1845C>A p.L615= (on ENST00000506720 / NM_001322402.2; = p.L547= on NM_015236.6) | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV101547299; called by muse, varscan2
- AGFG1 | c.462A>C p.T154= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100029168; called by muse, mutect2, varscan2
- AHNAK2 | c.8199G>A p.K2733= | Silent (SNP) | VAF 172/392 reads (44%) | catalogued as rs573895492, COSV100318867; called by muse, mutect2, varscan2
- ALG10B | c.69C>A p.L23= | Silent (SNP) | VAF 178/414 reads (43%) | catalogued as COSV100439998; called by muse, mutect2, varscan2
- ARHGAP27 | c.1092C>T p.P364= (on ENST00000428638 / NM_001282290.1; = p.P23= on NM_199282.3) | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as COSV100976620; called by muse, mutect2, varscan2
- ARMH4 | c.981C>T p.T327= | Silent (SNP) | VAF 94/231 reads (41%) | catalogued as COSV99958970; called by muse, mutect2, varscan2
- ATP6V0A4 | c.258G>T p.L86= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV100023663; called by muse, mutect2, varscan2
- ATP6V1F | c.78G>A p.G26= | Silent (SNP) | VAF 59/73 reads (81%) | catalogued as rs1375427260, COSV99926262; called by muse, mutect2, varscan2
- ATXN3L | c.912G>T p.P304= | Silent (SNP) | VAF 73/84 reads (87%) | catalogued as COSV101019585; called by muse, mutect2, varscan2
- BCR | c.3525C>T p.N1175= | Silent (SNP) | VAF 103/205 reads (50%) | catalogued as rs1235462585, COSV100007025; called by muse, mutect2, varscan2
- BTBD11 | c.1758G>A p.K586= (on ENST00000280758 / NM_001018072.2; = p.K123= on NM_001017523.2) | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as COSV99776930; called by muse, mutect2
- C11orf24 | c.825C>T p.P275= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs979939030, COSV100422692; called by muse, mutect2, varscan2
- C1orf162 | c.261T>A p.L87= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as COSV100636244; called by muse, mutect2, varscan2
- C22orf23 | c.327G>A p.E109= | Silent (SNP) | VAF 19/220 reads (9%) | catalogued as COSV99317508; called by muse, mutect2
- CABS1 | c.204G>A p.L68= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs1363144341, COSV99909198; called by muse, mutect2, varscan2
- CACNG6 | c.690C>A p.I230= (on ENST00000252729 / NM_145814.1; = p.I159= on NM_031897.2) | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV99403646; called by muse, mutect2, varscan2
- CCDC186 | c.579G>A p.L193= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs956862570, COSV100991050; called by muse, mutect2, varscan2
- CCDC83 | c.30G>A p.K10= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV54705636, COSV99721971; called by muse, mutect2
- CD163 | c.510A>T p.G170= | Silent (SNP) | VAF 161/361 reads (45%) | catalogued as COSV100776113; called by muse, mutect2, varscan2
- CLMP | c.645G>A p.G215= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV101507458; called by muse, mutect2, varscan2
- CLSTN3 | c.309G>A p.K103= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99867663; called by muse, mutect2, varscan2
- CNGA3 | c.1311T>C p.V437= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV99737414; called by muse, mutect2, varscan2
- COL14A1 | c.2730C>A p.A910= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV52850832; called by muse, mutect2, varscan2
- COL7A1 | c.6999A>T p.G2333= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100097635; called by muse, mutect2, varscan2
- CTSA | c.831C>G p.L277= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as COSV99510132; called by muse, mutect2, varscan2
- CUL9 | c.5652G>T p.G1884= | Silent (SNP) | VAF 41/124 reads (33%) | catalogued as COSV99336024; called by muse, mutect2, varscan2
- CYP2C9 | c.1437G>C p.V479= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as COSV99583179; called by muse, mutect2
- DARS1 | c.276G>A p.A92= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs746768443, COSV99927900; called by muse, mutect2, varscan2
- DCDC1 | c.5100C>G p.L1700= (on ENST00000597505 / NM_001367979.1; = p.L807= on NM_020869.3) | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV100360775; called by muse, mutect2, varscan2
- DEAF1 | c.342C>T p.F114= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs867499392, COSV100102295; called by muse, mutect2, varscan2
- DGCR2 | c.1425C>G p.V475= | Silent (SNP) | VAF 38/386 reads (10%) | catalogued as COSV99593957; called by muse, mutect2
- DHX15 | c.552C>T p.P184= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100391730; called by muse, mutect2, varscan2
- DMD | c.8118A>T p.T2706= | Silent (SNP) | VAF 28/36 reads (78%) | catalogued as COSV100629193; called by muse, mutect2, varscan2
- DOCK5 | c.717A>T p.A239= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99377811; called by muse, mutect2, varscan2
- DTX1 | c.186G>A p.L62= | Silent (SNP) | VAF 63/174 reads (36%) | catalogued as rs1475623744, COSV99986525; called by muse, mutect2, varscan2
- DUOX2 | c.2022C>A p.V674= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV101199888; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1416G>A p.L472= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV100668837; called by muse, mutect2
- EPHB1 | c.747T>C p.P249= | Silent (SNP) | VAF 125/292 reads (43%) | catalogued as COSV101214333; called by muse, mutect2, varscan2
- EPHB3 | c.2169C>G p.L723= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV100383275; called by muse, mutect2, varscan2
- EPHB4 | c.1341C>T p.P447= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs772073456, COSV100639643; called by muse, mutect2, varscan2
- ESD | c.834A>G p.K278= | Silent (SNP) | VAF 51/62 reads (82%) | catalogued as COSV101099226; called by muse, mutect2, varscan2
- FAM131A | c.858C>T p.P286= (on ENST00000310585; = p.P317= on NM_144635.5) | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs375453499, COSV99658964; called by muse, mutect2, varscan2
- FAM217A | c.564G>A p.L188= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99212804; called by muse, mutect2, varscan2
- FAM47B | c.1026C>A p.S342= | Silent (SNP) | VAF 38/48 reads (79%) | catalogued as COSV100264272; called by muse, mutect2, varscan2
- FASTKD1 | c.12A>C p.T4= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV101328543, COSV101328546; called by muse, mutect2, varscan2
- FES | c.1635G>A p.L545= | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as rs142500116; called by muse, mutect2
- FEZF2 | c.876C>T p.L292= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99334997; called by muse, mutect2, varscan2
- FRMPD1 | c.4137C>T p.P1379= | Silent (SNP) | VAF 64/94 reads (68%) | catalogued as COSV100899626, COSV66703513; called by muse, mutect2, varscan2
- FRMPD2 | c.1833G>A p.G611= | Silent (SNP) | VAF 67/183 reads (37%) | catalogued as rs770095462, COSV100564160, COSV59720553; called by muse, mutect2, varscan2
- GABRA4 | c.81G>T p.A27= | Silent (SNP) | VAF 95/126 reads (75%) | catalogued as COSV51928752, COSV99974658; called by muse, mutect2
- GALNT17 | c.51G>T p.A17= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as rs748838896, COSV100356049; called by muse, varscan2
- GPR132 | c.372C>T p.C124= | Silent (SNP) | VAF 114/329 reads (35%) | catalogued as COSV100317723; called by muse, mutect2, varscan2
- GPR50 | c.1728C>A p.A576= | Silent (SNP) | VAF 83/108 reads (77%) | catalogued as COSV99506631; called by muse, mutect2, varscan2
- H3C11 | c.72G>A p.K24= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV100138076; called by muse, mutect2, varscan2
- HAL | c.604C>T p.L202= | Silent (SNP) | VAF 13/325 reads (4%) | catalogued as rs937776146, COSV99701646; called by muse, mutect2
- HIP1R | c.1914C>T p.A638= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs753717852, COSV99459246; called by muse, mutect2, varscan2
- HOXB8 | c.138C>T p.G46= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99494187; called by muse, mutect2, varscan2
- IGF1R | c.246C>T p.T82= | Silent (SNP) | VAF 16/376 reads (4%) | catalogued as rs1218418397, COSV99162657; called by muse, mutect2
- IGHV3-74 | c.126A>G p.A42= | Silent (SNP) | VAF 68/174 reads (39%) | called by muse, mutect2, varscan2
- IKBKE | c.2025A>G p.T675= | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV100898009; called by muse, mutect2, varscan2
- IL1A | c.253C>A p.R85= | Silent (SNP) | VAF 88/228 reads (39%) | catalogued as COSV54519044, COSV99641501; called by muse, mutect2, varscan2
- INPP4B | c.2622A>C p.R874= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as COSV99526665; called by muse, mutect2, varscan2
- ITIH5 | c.1539C>T p.I513= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV53661604, COSV99905683; called by muse, mutect2, varscan2
- ITPRID1 | c.3078T>A p.G1026= | Silent (SNP) | VAF 110/134 reads (82%) | catalogued as COSV100087445; called by muse, mutect2, varscan2
- KCNA5 | c.1191C>T p.A397= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV52908440, COSV99364187; called by muse, mutect2, varscan2
- KCNA5 | c.1296G>A p.R432= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs771709032, COSV99364189; called by muse, mutect2, varscan2
- KLHL41 | c.1047G>A p.V349= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as COSV99500602; called by muse, mutect2
- KMT2D | c.9180G>A p.G3060= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99985552; called by muse, mutect2, varscan2
- LAMP5 | c.414G>A p.L138= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV55715680, COSV99855698; called by muse, mutect2, varscan2
- LIFR | c.2937G>C p.S979= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as COSV54700234, COSV99665426; called by muse, mutect2, varscan2
- LIG1 | c.1869G>T p.V623= | Silent (SNP) | VAF 53/236 reads (22%) | catalogued as COSV99619341; called by muse, mutect2, varscan2
- LIPG | c.714C>T p.H238= | Silent (SNP) | VAF 58/68 reads (85%) | catalogued as COSV99724727; called by muse, mutect2, varscan2
- LIPG | c.1311C>A p.P437= | Silent (SNP) | VAF 27/32 reads (84%) | catalogued as COSV99724730; called by muse, mutect2, varscan2
- LPCAT1 | c.1341G>T p.T447= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV99359344; called by muse, mutect2, varscan2
- LRRC28 | c.726G>A p.V242= | Silent (SNP) | VAF 39/468 reads (8%) | catalogued as COSV100113850; called by muse, mutect2
- LRRC32 | c.93G>A p.K31= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV99477287; called by muse, varscan2
- LRRTM1 | c.15G>A p.L5= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs1364175891, COSV54443203; called by muse, mutect2, varscan2
- LTN1 | c.5025G>A p.Q1675= | Silent (SNP) | VAF 132/321 reads (41%) | catalogued as COSV100798192; called by muse, mutect2, varscan2
- MAGED1 | c.837A>T p.P279= | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV100431806; called by muse, mutect2, varscan2
- MAP7D3 | c.87G>A p.E29= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV100286690, COSV60172715; called by muse, mutect2, varscan2
- MARS2 | c.564A>T p.P188= | Silent (SNP) | VAF 70/164 reads (43%) | catalogued as COSV99986694; called by muse, mutect2, varscan2
- MCC | c.2409C>T p.T803= | Silent (SNP) | VAF 38/57 reads (67%) | catalogued as rs1249571346, COSV100203176; called by muse, mutect2, varscan2
- MCEMP1 | c.255C>T p.S85= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs867829942, COSV100365437; called by muse, mutect2, varscan2
- MCM10 | c.1849C>T p.L617= (on ENST00000484800 / NM_182751.3; = p.L616= on NM_018518.5) | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV101098439; called by muse, mutect2, varscan2
- MMP16 | c.1326C>A p.A442= | Silent (SNP) | VAF 19/198 reads (10%) | catalogued as rs1365681090, COSV99690286; called by muse, mutect2
- MMP26 | c.66T>A p.P22= | Silent (SNP) | VAF 73/101 reads (72%) | catalogued as COSV100332254; called by muse, mutect2, varscan2
- MROH2B | c.4560C>A p.I1520= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV101270438, COSV68187594; called by muse, mutect2, varscan2
- MROH2B | c.667C>A p.R223= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs767719732, COSV101270905, COSV68188772; called by muse, mutect2, varscan2
- MYH1 | c.4371G>C p.L1457= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as rs780203692, COSV99876817; called by muse, mutect2, varscan2
- MYO10 | c.5982C>T p.F1994= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV99946219; called by muse, mutect2, varscan2
- MYO18B | c.1959C>T p.D653= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100125093; called by muse, mutect2, varscan2
- NARS2 | c.138C>T p.I46= | Silent (SNP) | VAF 69/271 reads (25%) | catalogued as rs779033468, COSV99807532; called by muse, mutect2, varscan2
- NCKAP5 | c.4863C>G p.L1621= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100494291, COSV58474383; called by muse, mutect2, varscan2
- NCOR1 | c.318G>C p.S106= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99251933; called by muse, mutect2, varscan2
- NDST4 | c.1164C>T p.L388= | Silent (SNP) | VAF 39/40 reads (98%) | catalogued as COSV99997795; called by muse, mutect2, varscan2
- NEBL | c.1458T>C p.Y486= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as COSV101009346; called by muse, mutect2, varscan2
- NOMO2 | c.1167C>G p.V389= | Silent (SNP) | VAF 160/282 reads (57%) | catalogued as COSV100395810; called by muse, mutect2, varscan2
- NOVA1 | c.390A>C p.T130= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV99948636; called by muse, mutect2, varscan2
- NPAP1 | c.1698C>G p.T566= | Silent (SNP) | VAF 69/126 reads (55%) | catalogued as COSV100276149; called by muse, mutect2, varscan2
- OR14A16 | c.342G>A p.T114= | Silent (SNP) | VAF 94/168 reads (56%) | catalogued as rs777222344, COSV62927696; called by muse, mutect2, varscan2
- OR2T27 | c.189C>G p.L63= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV100788396; called by muse, mutect2, varscan2
- OR4C15 | c.612G>A p.G204= (on ENST00000314644; = p.G150= on NM_001001920.2) | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as rs372501267, COSV100116085; called by muse, mutect2, varscan2
- OR6B2 | c.828C>A p.A276= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as COSV53156994, COSV99401742; called by muse, mutect2, varscan2
- OR9Q2 | c.420C>T p.A140= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs377268144; called by muse, mutect2, varscan2
- OTUD7B | c.2481G>C p.L827= | Silent (SNP) | VAF 43/209 reads (21%) | catalogued as COSV100967777; called by muse, mutect2, varscan2
- PARP4 | c.4923A>G p.E1641= | Silent (SNP) | VAF 40/49 reads (82%) | catalogued as COSV67962288; called by muse, mutect2, varscan2
- PATE1 | c.27C>T p.L9= | Silent (SNP) | VAF 75/128 reads (59%) | catalogued as rs770881751, COSV99986233; called by muse, mutect2, varscan2
- PCDHB16 | c.1737G>C p.A579= | Silent (SNP) | VAF 97/113 reads (86%) | catalogued as COSV99502821; called by muse, mutect2, varscan2
- PCK1 | c.771G>A p.E257= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as rs1467468657, COSV100100938; called by muse, mutect2, varscan2
- PCNT | c.4893C>T p.G1631= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as rs765995470, COSV100856015; called by muse, mutect2, varscan2
- PDE4DIP | c.5766C>A p.S1922= | Silent (SNP) | VAF 54/113 reads (48%) | catalogued as COSV100521666, COSV57707382; called by muse, mutect2, varscan2
- PGBD1 | c.1071C>T p.L357= | Silent (SNP) | VAF 49/123 reads (40%) | catalogued as rs1224673542, COSV99460910; called by muse, mutect2, varscan2
- PHF20L1 | c.2934C>T p.F978= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV55196112; called by muse, mutect2, varscan2
- PIK3CG | c.132G>A p.L44= | Silent (SNP) | VAF 137/153 reads (90%) | catalogued as COSV100783158; called by muse, mutect2, varscan2
- PKDREJ | c.2211C>T p.L737= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as rs949931055, COSV99479484; called by muse, mutect2, varscan2
- PLD4 | c.432G>A p.G144= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV101190554; called by muse, mutect2, varscan2
- PNN | c.9C>T p.V3= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV53766067; called by muse, mutect2
- POM121L12 | c.537G>A p.L179= | Silent (SNP) | VAF 76/85 reads (89%) | catalogued as rs745781136, COSV101374978; called by muse, mutect2, varscan2
- PRAG1 | c.1278T>G p.P426= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100422780; called by muse, mutect2, varscan2
- PTGER2 | c.417G>T p.G139= | Silent (SNP) | VAF 77/206 reads (37%) | catalogued as COSV99817738; called by muse, mutect2, varscan2
- PTPRS | c.3000G>A p.L1000= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99512300; called by muse, mutect2, varscan2
- RALGAPA2 | c.1071G>A p.Q357= | Silent (SNP) | VAF 47/116 reads (41%) | catalogued as rs771717957, COSV52497539, COSV99174949; called by muse, mutect2, varscan2
- RAPGEF1 | c.477C>T p.Y159= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100940743; called by muse, mutect2, varscan2
- REG1A | c.97C>A p.R33= | Silent (SNP) | VAF 140/387 reads (36%) | catalogued as COSV52069280, COSV52069979; called by muse, mutect2, varscan2
- RIPOR1 | c.2712C>T p.V904= (on ENST00000379312 / NM_001193522.2; = p.V900= on NM_024519.4) | Silent (SNP) | VAF 11/235 reads (5%) | catalogued as COSV99243619; called by muse, mutect2
- RNF146 | c.729G>A p.L243= (on ENST00000368314 / NM_001242850.2; = p.L242= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV100541901; called by muse, mutect2, varscan2
- RNF8 | c.186C>T p.N62= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as COSV100009883; called by muse, mutect2, varscan2
- RYR3 | c.9018C>T p.H3006= (on ENST00000389232; = p.H3007= on NM_001036.6) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs769276514, COSV101214406; called by muse, mutect2, varscan2
- RYR3 | c.13089C>T p.Y4363= (on ENST00000389232; = p.Y4364= on NM_001036.6) | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101214408; called by muse, mutect2, varscan2
- SEMA6B | c.1245G>C p.A415= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100015113; called by muse, mutect2, varscan2
- SLC29A3 | c.639C>G p.A213= | Silent (SNP) | VAF 81/208 reads (39%) | catalogued as COSV100928592; called by muse, mutect2, varscan2
- SLC30A1 | c.183C>T p.A61= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100879164; called by muse, mutect2, varscan2
- SLC39A12 | c.621G>A p.Q207= | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as rs368515548, COSV101070144; called by muse, mutect2, varscan2
- SLC49A4 | c.240C>A p.R80= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV99659254; called by muse, mutect2, varscan2
- SLC5A11 | c.144G>A p.V48= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV61739739; called by muse, mutect2, varscan2
- SLC5A11 | c.1506G>A p.V502= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV100762911; called by muse, mutect2, varscan2
- SLC6A19 | c.852G>A p.G284= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as rs910001858, COSV100443763; called by muse, mutect2, varscan2
- SLIT1 | c.1596C>G p.T532= | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as COSV99822441; called by muse, mutect2, varscan2
- SLITRK3 | c.1713C>A p.V571= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV99580126; called by muse, mutect2, varscan2
- SLTM | c.2052G>A p.L684= | Silent (SNP) | VAF 80/147 reads (54%) | catalogued as COSV99989388; called by muse, mutect2, varscan2
- SMG1 | c.5388C>A p.L1796= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as COSV101246778; called by muse, mutect2, varscan2
- SORCS3 | c.3600C>A p.V1200= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100865641, COSV63803556; called by muse, mutect2, varscan2
- SOX14 | c.654C>T p.Y218= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1464971765, COSV100048333, COSV60163392; called by muse, mutect2, varscan2
- SPAG4 | c.1020G>C p.P340= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV100958342; called by muse, mutect2, varscan2
- SPTA1 | c.4129A>C p.R1377= | Silent (SNP) | VAF 77/193 reads (40%) | catalogued as COSV100935532; called by muse, mutect2, varscan2
- ST3GAL5 | c.693C>T p.F231= (on ENST00000377332; = p.F271= on NM_003896.4) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100088731, COSV60385715; called by muse, mutect2, varscan2
- SYNM | c.3825G>A p.G1275= | Silent (SNP) | VAF 22/664 reads (3%) | catalogued as COSV100019254; called by muse, mutect2
- TAP1 | c.2274C>T p.L758= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100841310; called by muse, mutect2, varscan2
- TBX10 | c.261C>T p.V87= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100106001; called by muse, mutect2, varscan2
- THNSL1 | c.1179A>C p.L393= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100896308; called by muse, mutect2, varscan2
- TLR2 | c.1767A>C p.A589= | Silent (SNP) | VAF 89/101 reads (88%) | catalogued as COSV99472533; called by muse, mutect2, varscan2
- TMEM135 | c.147A>T p.A49= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100450151; called by muse, mutect2, varscan2
- TMEM215 | c.183G>A p.R61= | Silent (SNP) | VAF 49/65 reads (75%) | catalogued as rs1304342908, COSV100713254; called by muse, mutect2, varscan2
- TNKS | c.2658G>T p.A886= | Silent (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2
- TNRC18 | c.5355C>T p.P1785= | Silent (SNP) | VAF 29/34 reads (85%) | catalogued as COSV101269874; called by muse, mutect2, varscan2
- TRGV5 | c.243C>G p.L81= | Silent (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1575C>T p.S525= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as COSV53675665; called by muse, mutect2, varscan2
- TTN | c.86967C>G p.T28989= (on ENST00000591111; = p.T21565= on NM_003319.4) | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV100628878; called by muse, mutect2, varscan2
- TTN | c.16197C>T p.G5399= (on ENST00000591111; = p.G4472= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as rs1027103829, COSV100628902, COSV59907280; called by muse, mutect2, varscan2
- TTN | c.1611T>A p.T537= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100628907; called by muse, mutect2, varscan2
- TULP4 | c.3765G>T p.L1255= | Silent (SNP) | VAF 162/195 reads (83%) | catalogued as COSV100893820; called by muse, mutect2, varscan2
- TXNRD1 | c.546C>T p.A182= (on ENST00000525566 / NM_001093771.3; = p.A84= on NM_003330.4) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs755296672, COSV100723566; called by muse, varscan2
- UAP1 | c.52C>T p.L18= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV99618056; called by muse, mutect2, varscan2
- UBR4 | c.12402C>T p.F4134= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100921795; called by muse, mutect2
- UBXN2B | c.630G>A p.L210= | Silent (SNP) | VAF 41/69 reads (59%) | catalogued as rs755048909, COSV101275591; called by muse, mutect2, varscan2
- UGT2A3 | c.180G>A p.K60= | Silent (SNP) | VAF 80/92 reads (87%) | catalogued as rs367829474; called by muse, mutect2, varscan2
- ZCCHC8 | c.1695C>T p.L565= | Silent (SNP) | VAF 71/370 reads (19%) | catalogued as COSV100288850; called by muse, mutect2, varscan2
- ZNF14 | c.1920G>A p.E640= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100694130; called by muse, mutect2, varscan2
- ZNF257 | c.1107G>A p.E369= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101448161; called by muse, mutect2, varscan2
- ZNF471 | c.1839C>G p.S613= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV100340856; called by muse, mutect2
- ZNF486 | c.243C>G p.A81= | Silent (SNP) | VAF 41/81 reads (51%) | catalogued as COSV100631474; called by muse, mutect2, varscan2
- ZNF559 | c.1545T>C p.H515= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100416733; called by muse, mutect2, varscan2
- ZNF827 | c.3012G>A p.G1004= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV65233569; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498336 G>A | 5'Flank (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.1354-1169G>A | Intron (SNP) | VAF 19/57 reads (33%) | catalogued as COSV60715529; called by muse, mutect2, varscan2
- C14orf178 | n.540C>T | RNA (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100575710; called by muse, mutect2, varscan2
- C8orf86 | n.794G>T | RNA (SNP) | VAF 35/109 reads (32%) | catalogued as COSV100817585, COSV63935450; called by muse, mutect2, varscan2
- CPLANE1 | chr5:37164272 C>A | 3'Flank (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99951641; called by muse, mutect2, varscan2
- CPLANE1 | c.*5176C>T | 3'UTR (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99951650; called by muse, mutect2, varscan2
- EML2 | c.21-152C>T | Intron (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99840437; called by muse, mutect2
- KCNK12 | c.*8569G>A | 3'UTR (SNP) | VAF 20/35 reads (57%) | catalogued as rs901708619, COSV100010033; called by muse, mutect2, varscan2
- KIR3DX1 | n.788G>C | RNA (SNP) | VAF 30/99 reads (30%) | catalogued as COSV99683628; called by muse, mutect2, varscan2
- KLK8 | c.71-88C>T | Intron (SNP) | VAF 36/85 reads (42%) | catalogued as COSV51595498; called by muse, mutect2, varscan2
- LINC00482 | n.971G>A | RNA (SNP) | VAF 17/34 reads (50%) | catalogued as rs1300394376; called by muse, mutect2, varscan2
- LINC01098 | n.778A>T | RNA (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- LRRC27 | c.1073+1164C>T | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100689951; called by muse, mutect2, varscan2
- MICAL3 | c.2242-774C>G | Intron (SNP) | VAF 11/143 reads (8%) | catalogued as COSV99262828; called by muse, mutect2
- MIR527 | n.30T>G | RNA (SNP) | VAF 25/207 reads (12%) | called by muse, mutect2, varscan2
- MIR770 | n.74G>T | RNA (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- SLC26A9 | c.*181C>T | 3'UTR (SNP) | VAF 22/47 reads (47%) | catalogued as COSV100536753; called by muse, mutect2, varscan2
- SPATA8 | n.274A>T | RNA (SNP) | VAF 13/213 reads (6%) | catalogued as COSV100139097; called by muse, mutect2
- SPEN | c.404+981G>A | Intron (SNP) | VAF 13/18 reads (72%) | catalogued as COSV101005577; called by muse, mutect2
- SSPOP | n.14546G>T | RNA (SNP) | VAF 21/26 reads (81%) | catalogued as COSV100948007; called by muse, mutect2, varscan2
- STMP1 | chr7:135660515 G>A | 5'Flank (SNP) | VAF 13/145 reads (9%) | called by muse, mutect2
- TMC5 | c.1049-3335A>T | Intron (SNP) | VAF 46/84 reads (55%) | catalogued as COSV99572847; called by muse, mutect2, varscan2
- TTN | c.10360+1519C>A | Intron (SNP) | VAF 59/170 reads (35%) | catalogued as COSV100628905; called by muse, mutect2, varscan2
- XIRP2 | c.*1342G>A | 3'UTR (SNP) | VAF 6/105 reads (6%) | catalogued as COSV99746945, COSV99747093; called by muse, mutect2
